CPTAC case C3N-02061 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e15384a3-a3a9-421e-89b7-0ba1af9d71ae

Demographics
Sex at birth: female; Race: white; Year of birth: 1949; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 67.8 years (24,760 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 54 days; Progression or recurrence: no; Days to last follow up: 54 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 10; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 54 days; Disease response: Tumor Free.
- Days to follow up: 54 days; Disease response: Complete Response.

Other clinical attributes
- Weight: 92 kg; Height: 150 cm; BMI: 40.89; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02061-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 37 days; Initial weight: 360 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02061-22: Section location: Entire uterine cavity; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-02061-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 37 days; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02061-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 37 days; Method of sample procurement: Blood Draw.
